Gene-level copy-number profile of tumor specimen TCGA-YR-A95A-01A from TCGA case TCGA-YR-A95A, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 52.8 years (19,292 days).
Specimen TCGA-YR-A95A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.503efef1-62b1-4f49-9696-0ad297b9139b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YR-A95A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa07ed3b-28ee-48b9-adf0-458b67534c9b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 10,717; copy number 2: 48,314; copy number 3: 754.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YR-A95A-01A-12D-A416-01): tumor purity 0.75, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:121,679,972–121,858,768, 3 genes: RPL23AP48, AL603865.1, HMGB3P18.
- chr6:163,306,907–164,009,980, 10 genes (within-gene range 0–1): PACRG-AS1, AL031121.2, AL031121.3, AL031121.1, CAHM, QKI, AL445307.1, AL078602.1, AL137005.1, RN7SL366P.
- chr6:164,928,191–165,309,605, 3 genes (within-gene range 0–1): AL133538.1, AL136100.1, C6orf118.
- chr6:167,644,479–168,101,511, 14 genes: AL356123.1, LINC02538, AL356123.2, LINC02487, AL009178.1, LINC01558, AL009178.2, AL009178.3, AFDN-DT, AFDN, HGC6.3, KIF25-AS1, KIF25, FRMD1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
